Gene-level copy-number profile of tumor specimen C3N-02224-02 from CPTAC case C3N-02224, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Tumor grade: G2.
Specimen C3N-02224-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 23512021-03b1-4fdc-a8ef-82eee6c091fe.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02224-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/0c753d9e-18a8-46f0-9b4c-eb3077e864fe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,780; copy number 2: 56,624.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,780. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
